Somatic mutation profile of tumor specimen TCGA-EM-A3O6-01A (aliquot TCGA-EM-A3O6-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3O6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 54.4 years (19,856 days).
Specimen TCGA-EM-A3O6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34937246-e1a8-41b4-82a8-4225f1cce3ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3O6-10A (Blood Derived Normal), aliquot TCGA-EM-A3O6-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93cb421a-e6d9-4be3-94db-693aa0bc2da6

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 60/324 reads (19%) | catalogued as COSV62394791; called by muse, mutect2, varscan2
- MARCHF6 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56881702; called by muse, mutect2, varscan2
- MYO6 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64119101; called by muse, mutect2
- NEB | c.8616C>G p.H2872Q | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51418535; called by muse, mutect2
- PDGFRB | c.2413G>A p.G805S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as COSV55804964; called by muse, mutect2, varscan2
- PHF8 | c.401+1G>T p.X134_splice (on ENST00000357988 / NM_001184896.1; = p.X98_splice on NM_015107.3) | Splice Site (SNP) | VAF 33/122 reads (27%) | catalogued as COSV57681873; called by muse, mutect2, varscan2
- PIK3R1 | c.1850C>G p.P617R (on ENST00000521381 / NM_181523.3; = p.P347R on NM_181504.4) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV57130592; called by muse, mutect2, varscan2
- PTEN | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs121909239, CM051216, CM159947, COSV64289881, COSV64296805, COSV64297163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APAF1 | c.3599del p.K1200Sfs*34 (on ENST00000551964 / NM_181861.2; = p.K1146Sfs*34 on NM_001160.3) | Frame Shift Del (DEL) | VAF 35/108 reads (32%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.219G>A p.A73= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs147430340; called by muse, mutect2, varscan2
- CASZ1 | c.2652C>T p.A884= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100681523, COSV59735752; called by muse, mutect2, varscan2
- ZNF669 | c.792A>C p.S264= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV58537714; called by muse, mutect2
